Surgical pathology report (de-identified scan), TCGA case TCGA-80-5607, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR)/Ottawa, specimen TCGA-80-5607-01A (Primary Tumor).

[page 1 of 4]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details	
Sample Number	Sample Type
	BUFFY
	TUMOUR

[page 2 of 4]
					Histology and staging			
Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)
FF		Adenocarci						RESECT
FF	LUL lung le	Adenocarci						RESECT

[page 3 of 4]
Tumour Size (cm)	Histology	Grade/ Differentiation	Pathologic al T	Pathologic al N	Clinical M	VALCSG Stage	Histology Comments	Slide URL
LUL	3.50	03	II	T2,NOS	N1	M0		
LUL	3.50	03	II	T2,NOS	N1	M0		

Source: NCI Genomic Data Commons file d65edaa9-9292-426d-8560-db222ad25c10 (TCGA-80-5607.6C775590-55A2-4E85-B511-AFD2FA76CABC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).